Surgical pathology report (de-identified scan), TCGA case TCGA-LP-A5U3, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site ILSBIO, specimen TCGA-LP-A5U3-01A (Primary Tumor).

[page 1 of 6]
Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-O-3
Carcinoma, squamous cell
non-keratinizing NOS
8072/3
Site Cervix Uteri,
Cervix NOS C53.9
JW 4/2/13

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
Gender	Weight	☐ Single ☒ Married	Vietnam	36
☐ Male ☒ Female	50	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
			120/70	71

HISTORY OF PRESENT ILLNESS
Chief Complaints: Menorrhagia
Symptoms: Menorrhagia for 2 months
Clinical Findings: Vulva, vaginal were normal. tumour on posterior cervical lip, uterus was normal.
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☒ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
no				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
NA			

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		3
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal	2007 menorrhagia	3
Birth Control: ☐ Condom ☐ Oral Contraceptive ☒ IUD ☐ Other:		☐ Hormone Replacement Therapy: NA

SOCIAL HISTORY				
Occupation:		Environmental Hazards: NA		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
Normal		

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive:		CEA	☐ Negative ☐ Positive:	NA	
Hep B	☒ Negative ☐ Positive:		CA 15-3	☐ Negative ☐ Positive:	NA	
Hep C	☐ Negative ☐ Positive:	NA	CA 19-9	☐ Negative ☐ Positive:	NA	
AFP	☐ Negative ☐ Positive:	NA	PSA	☐ Negative ☐ Positive:	NA	
Other:	☐ Negative ☐ Positive:	NA	Other:	☐ Negative ☐ Positive:	NA	
B/T Cell Markers: NA						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound	normal	
X-Ray (mvs)	normal	
CT	no	
Endoscopy	no	
MRI	no	
Biopsy	Squamous cell carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Cervical cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
no	no	
Clinical Staging		Date of Diagnosis
T	N	M
Stage: T1a N0 M0		

Treatment Information = IA

SURGICAL TREATMENT			
Procedure			Date of Procedure
Radical hysterectomy			
Primary Tumor			
Organ	Detailed Location	Size	
Cervix	on posterior lip	1.8 x 0.8 x 0.8 cm	
Extension of Tumor			
limited to posterior lip			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes	no		
Dissected Lymph Nodes	no		
Distant Metastasis			
Organ	Detailed Location	Size	
no			
Surgical Staging			
T	N	M	Stage: T1a N0 M0 = IA

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
no				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: _ Date: _ Time: _

Preserved by: _ Date: _ Time: _

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
1	1	1	1	1		1	1
Time to LN2		Time to Formalin		Time to LN2			
25 min		20 min		16 min			

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Cervix	1.2 x 0.8 x 0.8 cm	posterior lip	0.2 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
no	no		
Distant Metastasis			
Organ	Detailed Location	Size	
no			
Pathological Staging			
pT	N	M	Stage: T1a No Mo - 2A
Notes:			

[page 5 of 6]
Microscopic Description

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse	+	-	+	-	Streaming	+	-	+	-		
Mosaic	+	-	+	-	Storiform	+	-	+	-		
Necrosis	+	-	+	-	Fibrosis	+	-	+	-		
Lymphocytic Infiltration	+	-	+	-	Palisading	+	-	+	-		
Vascular Invasion	+	-	+	-	Cystic Degeneration	+	-	+	-		
Clusterized	+	-	+	-	Bleeding	+	-	+	-		
Alveolar Formation	+	-	+	-	Myxoid Change	+	-	+	-		
Indian File	+	-	+	-	Psammoma/Calcification	+	-	+	-		

Cellular Differentiation																			
Squamous			+	-	Adenomatous			+	-	Sarcomatous			+	-	Lymphomatous			+	-
Squamoid Cell	+	-	+	-	Glandular cell	+	-	+	-	Round Cell	+	-	+	-	Large Cell	+	-	+	-
Spindle Cell	+	-	+	-	Cell Stratification	+	-	+	-	Fibroblast	+	-	+	-	Small Cell	+	-	+	-
Keratin	+	-	+	-	Secretion	+	-	+	-	Osteoblast	+	-	+	-	RS Cell/RS Like	+	-	+	-
Desmosome	+	-	+	-	Intracyt. Vacuole	+	-	+	-	Lipoblast	+	-	+	-	Inflam. Cell	+	-	+	-
Pearl	+	-	+	-	Gland formation	+	-	+	-	Myoblast	+	-	+	-	Plasma Cell	+	-	+	-

Cellular Differentiation:				
Well		Moderate		Poor
Nuclear Appearance				
Nuclear Atypia:		0	I	II
Aniso Nucleosis				
Hyperchromatism				
Nucleolar Prominent				
Multinucleated Giant Cell				
Mitotic Activity				
Nuclear Grade:				

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive	100	
PR	☐ Negative ☐ Positive	100	
Her-2/neu	☐ Negative ☐ Positive	100	
B-Cell Marker	☐ Negative ☐ Positive	100	
T-Cell Marker	☐ Negative ☐ Positive	100	
Other:	☐ Negative ☐ Positive	100	
Other:	☐ Negative ☐ Positive	100	

Final Pathology Report

Histological Diagnosis: Squamous cell carcinoma Grade: II

Comments:

Principal Investigator

Pathologist

Date _____

[page 6 of 6]
Consolidated Pathology Diagnosis

Histological Pattern											
Cell Distribution			Structural Pattern			Cellular Differentiation			Nuclear Appearance		
	+	-		+	-		+	-		+	-
Diffuse		☒	Streaming			Squamous			Adenomatous		
Mosaic	☒		Storiform			Squamoid Cell	☒		Glandular cell		
Necrosis		☒	Fibrosis			Spindle Cell	☒		Cell Stratification		
Lymphocytic Infiltration	☒		Palisading			Keratin	☒		Secretion		
Vascular Invasion		☒	Cystic Degeneration			Desmosome	☒		Intracyt. Vacuole		
Clusterized	☒		Bleeding			Pearl		☒	Gland formation		
Alveolar Formation		☒	Myxoid Change								
Indian File		☒	Psammoma/Calcification								
Cellular Differentiation											
Cellular Differentiation: ☐ Well ☐ Moderate ☒ Poor											
Nuclear Appearance											
Nuclear Atypia:			0		I		II		III		
Aniso Nucleosis									☒		
Hyperchromatism									☒		
Nucleolar Prominent									☒		
Multinucleated Giant Cell									☒		
Mitotic Activity									☒		
Nuclear Grade:									☒		

Final Pathology Report

Histological Diagnosis: nonkeratinizing Squamous **Grade:** 3
cell carcinoma

Comments:

D, 85%

Director, Research Pathology

Date

Criteria	W 2/17/13	Yes	No

Source: NCI Genomic Data Commons file c4d35407-032f-485b-95fc-66687d6c3322 (TCGA-LP-A5U3.153C30F0-1533-4056-9E90-F1568B8130D9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).